Somatic mutation profile of tumor specimen HCM-BROD-0417-C71-01A (aliquot HCM-BROD-0417-C71-01A-11D-A82H-36) from HCMI case HCM-BROD-0417-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.0 years (18,275 days).
Specimen HCM-BROD-0417-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec0ed662-c94a-4c66-b62b-5f62ca63ecda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0417-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0417-C71-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9049d166-1c60-489a-9215-8b96b7544e6f

The open-access MAF lists 57 somatic variants for this specimen: 46 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 9, Nonsense Mutation 4, Frame Shift Del 2, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 246/556 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AKR7A2 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 169/450 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs1458311650; called by muse, mutect2, varscan2
- ARHGEF17 | c.1851del p.G618Efs*9 | Frame Shift Del (DEL) | VAF 128/427 reads (30%) | catalogued as rs764619467; called by mutect2, pindel, varscan2
- DDX60L | c.4505C>G p.P1502R | Missense Mutation (SNP) | VAF 87/250 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99487591; called by muse, mutect2, varscan2
- FLNA | c.4909G>A p.V1637M | Missense Mutation (SNP) | VAF 279/746 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as rs1333867692, COSV61053313; called by muse, mutect2, varscan2
- FNDC1 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 117/274 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1031735872, COSV51949316; called by muse, mutect2, varscan2
- IGLV3-19 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 105/150 reads (70%) | catalogued as rs1264631654; called by muse, mutect2, varscan2
- KSR2 | c.1125C>A p.F375L | Missense Mutation (SNP) | VAF 166/932 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.009); catalogued as COSV56669188; called by muse, mutect2, varscan2
- LZTR1 | c.1576C>T p.Q526* | Nonsense Mutation (SNP) | VAF 240/360 reads (67%) | catalogued as rs768530578; called by muse, mutect2, varscan2
- NYX | c.214A>C p.N72H | Missense Mutation (SNP) | VAF 337/715 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM158331; called by muse, mutect2, varscan2
- OR10H5 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 168/385 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs149384614; called by muse, mutect2, varscan2
- OR5D16 | c.443T>A p.V148D | Missense Mutation (SNP) | VAF 189/464 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV65721821; called by muse, mutect2
- PTPN14 | c.2015G>A p.R672Q | Missense Mutation (SNP) | VAF 226/527 reads (43%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.978); catalogued as rs1336851908, COSV65281181; called by muse, varscan2
- TP53 | c.965del p.P322Hfs*23 | Frame Shift Del (DEL) | VAF 175/516 reads (34%) | catalogued as COSV52729459, COSV52826955; called by mutect2, pindel, varscan2
- TPP1 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 158/395 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs149986601; called by muse, mutect2, varscan2
- TRIM14 | c.1199G>A p.G400D | Missense Mutation (SNP) | VAF 314/775 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216598011; called by muse, mutect2, varscan2
- TTLL3 | c.2348G>C p.R783T | Missense Mutation (SNP) | VAF 100/230 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.049); catalogued as COSV59615343; called by muse, mutect2, varscan2
- USH1C | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 227/525 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs556221893, COSV99040689; called by muse, mutect2, varscan2
- WIZ | c.4200G>T p.K1400N (on ENST00000673675 / NM_001371589.1; = p.K305N on NM_021241.3) | Missense Mutation (SNP) | VAF 166/454 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV54609077; called by muse, mutect2, varscan2
- ZNF546 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 140/692 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV61257330; called by muse, mutect2, varscan2
- ALG9 | c.620G>A p.W207* | Nonsense Mutation (SNP) | VAF 111/282 reads (39%) | called by muse, mutect2, varscan2
- BTBD8 | c.3382G>A p.V1128I (on ENST00000636805 / NM_001376131.1; = p.V615I on NM_015237.4) | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CRISP3 | c.398T>A p.M133K (on ENST00000371159 / NM_001368123.1; = p.M115K on NM_006061.4) | Missense Mutation (SNP) | VAF 120/286 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- DCSTAMP | c.852G>A p.W284* | Nonsense Mutation (SNP) | VAF 173/433 reads (40%) | called by muse, mutect2, varscan2
- DST | c.3962C>G p.P1321R (on ENST00000361203 / NM_001374722.1; = p.P995R on NM_001723.6) | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FAT4 | c.3898A>G p.T1300A | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FRYL | c.2150T>G p.F717C | Missense Mutation (SNP) | VAF 85/226 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GAA | c.1897C>A p.Q633K | Missense Mutation (SNP) | VAF 157/342 reads (46%) | SIFT tolerated (0.93); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- GPR135 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 366/973 reads (38%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.015); called by muse, mutect2
- H3Y1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 130/317 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HOXA5 | c.365T>A p.L122Q | Missense Mutation (SNP) | VAF 349/1310 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- KCNJ6 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 159/411 reads (39%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- LOXHD1 | c.6484A>G p.T2162A (on ENST00000642948; = p.T2100A on NM_144612.7) | Missense Mutation (SNP) | VAF 178/476 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MALRD1 | c.1331G>C p.G444A | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); called by muse, mutect2
- MAN2B2 | c.1157T>G p.F386C | Missense Mutation (SNP) | VAF 302/757 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MSS51 | c.1042C>A p.P348T | Missense Mutation (SNP) | VAF 112/158 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OBSCN | c.773G>C p.S258T | Missense Mutation (SNP) | VAF 276/719 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHC2 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 155/389 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- PLSCR1 | c.482C>A p.T161N | Missense Mutation (SNP) | VAF 168/386 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.444); called by mutect2, varscan2
- PRKAR2B | c.1094C>G p.A365G | Missense Mutation (SNP) | VAF 172/619 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- SYTL4 | c.22T>A p.S8T | Missense Mutation (SNP) | VAF 11/267 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); called by muse, mutect2
- TMTC4 | c.162+1G>T p.X54_splice (on ENST00000376234 / NM_001350577.2; = p.X73_splice on NM_032813.5 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 90/119 reads (76%) | called by muse, mutect2, varscan2
- TRPM7 | c.2287C>G p.L763V | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- WNT2 | c.942C>A p.D314E | Missense Mutation (SNP) | VAF 227/727 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZBED1 | c.680C>G p.S227C | Missense Mutation (SNP) | VAF 371/900 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ZNF546 | c.2233G>T p.G745C | Missense Mutation (SNP) | VAF 81/549 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACTL9 | c.996G>A p.A332= | Silent (SNP) | VAF 249/640 reads (39%) | catalogued as rs1369590050, COSV61006527; called by muse, mutect2, varscan2
- CLCNKA | c.774C>T p.S258= | Silent (SNP) | VAF 118/291 reads (41%) | catalogued as COSV58892992; called by muse, mutect2, varscan2
- GPR119 | c.285G>C p.T95= | Silent (SNP) | VAF 276/672 reads (41%) | catalogued as COSV99358698; called by muse, mutect2, varscan2
- IQCH | c.1590C>T p.D530= | Silent (SNP) | VAF 137/353 reads (39%) | catalogued as rs763639911; called by muse, mutect2, varscan2
- IQSEC1 | c.1827G>A p.R609= | Silent (SNP) | VAF 147/453 reads (32%) | called by muse, mutect2, varscan2
- NOTCH4 | c.984C>T p.N328= | Silent (SNP) | VAF 364/912 reads (40%) | catalogued as rs770530863, COSV100900704; called by muse, mutect2, varscan2
- PKHD1L1 | c.7695C>G p.T2565= | Silent (SNP) | VAF 150/405 reads (37%) | called by muse, mutect2, varscan2
- PRRT4 | c.2613C>T p.A871= | Silent (SNP) | VAF 223/755 reads (30%) | catalogued as rs1193445284; called by muse, mutect2, varscan2
- TMEM132D | c.2445G>A p.G815= | Silent (SNP) | VAF 170/398 reads (43%) | called by muse, mutect2, varscan2
- PAX1 | c.287-188C>T | Intron (SNP) | VAF 214/536 reads (40%) | called by muse, mutect2, varscan2
- SIRPB1 | c.77-9911C>A | Intron (SNP) | VAF 133/169 reads (79%) | called by muse, mutect2, varscan2
